Somatic mutation profile of tumor specimen MMRF_1510_1_BM_CD138pos (aliquot MMRF_1510_1_BM_CD138pos_T1_KBS5U_L02847) from MMRF case MMRF_1510, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.6 years (21,402 days).
Specimen MMRF_1510_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dec6e75d-6967-472b-b9ba-8c4279133689.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1510_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1510_1_PB_Whole_C3_KBS5U_L02859; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e452ba65-63c1-4b33-b39e-c7c550683642

The open-access MAF lists 74 somatic variants for this specimen: 28 protein-altering or splice-affecting, 13 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, 3'UTR 19, Silent 13, Intron 7, 5'UTR 3, 5'Flank 2, In Frame Del 1, Splice Site 1, RNA 1, Nonsense Mutation 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2340A>C p.R780S | Missense Mutation (SNP) | VAF 39/72 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705753; called by muse, mutect2, varscan2
- ROBO3 | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121918270, CM041427, COSV101184923; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRE1 | c.2116C>T p.R706C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs774260084, COSV51677363; called by muse, mutect2, varscan2
- ATG9B | c.2092C>T p.R698C | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs751898474, COSV99871344; called by muse, mutect2, varscan2
- CCDC24 | c.551A>G p.Q184R | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs994201452; called by mutect2, varscan2
- DDR2 | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201041695, COSV63370870; called by muse, mutect2, varscan2
- DLX5 | c.824G>C p.G275A | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99756314; called by muse, varscan2
- GPRIN2 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.087); catalogued as rs1555019012; called by muse, mutect2, varscan2
- IGHV2-70D | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194006557; called by muse, varscan2
- IGLL5 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 27/29 reads (93%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs532234272, COSV73249744; called by muse, mutect2, varscan2
- LINGO2 | c.693G>C p.E231D | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV58060137; called by muse, mutect2, varscan2
- MYBPC3 | c.1187G>A p.W396* | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | catalogued as CM133950; called by muse, mutect2, varscan2
- OR4B1 | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 103/352 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs767081505, COSV58883552; called by muse, mutect2
- PER1 | c.1694T>C p.I565T | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.921); catalogued as rs1486648788; called by muse, mutect2, varscan2
- PNPT1 | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1433874162; called by muse, mutect2, varscan2
- RAPGEF1 | c.1411G>A p.G471S | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs758806260, COSV64699274; called by muse, mutect2, varscan2
- CILP2 | c.2601G>T p.R867S | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- EVX2 | c.888_917del p.A299_A308del | In Frame Del (DEL) | VAF 12/40 reads (30%) | called by mutect2, varscan2
- HELLS | c.53T>C p.V18A | Missense Mutation (SNP) | VAF 132/139 reads (95%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV1-69 | c.154_159dup p.A52_I53dup | In Frame Ins (INS) | VAF 16/42 reads (38%) | called by mutect2, varscan2
- IGHV2-70D | c.50T>G p.V17G | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, varscan2
- INTS8 | c.286T>G p.L96V | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- LAMA3 | c.5440_5448delinsC p.S1814Rfs*4 (on ENST00000313654 / NM_198129.4; = p.S205Rfs*4 on NM_000227.6) | Frame Shift Del (DEL) | VAF 34/100 reads (34%) | called by pindel, varscan2*
- LRRC8D | c.109A>T p.M37L | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- MEFV | c.1363A>C p.T455P | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- PUS3 | c.1270dup p.E424Gfs*10 | Frame Shift Ins (INS) | VAF 45/163 reads (28%) | called by mutect2, pindel, varscan2
- SEMA3E | c.277-1G>C p.X93_splice | Splice Site (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2, varscan2
- TRPC7 | c.836A>G p.D279G | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- AGBL5 | c.1197C>G p.L399= | Silent (SNP) | VAF 49/165 reads (30%) | called by muse, mutect2, varscan2
- ATP10D | c.1993C>A p.R665= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as rs142235555, COSV104385248; called by muse, mutect2, varscan2
- DNAH2 | c.1644G>A p.A548= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs765696484; called by muse, mutect2, varscan2
- EHMT2 | c.24A>G p.A8= | Silent (SNP) | VAF 2/8 reads (25%) | catalogued as rs868600151; called by muse, mutect2
- IGHV2-70D | c.339G>C p.T113= | Silent (SNP) | VAF 9/18 reads (50%) | called by muse, varscan2
- MMP27 | c.1473T>C p.Y491= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs968917983, COSV99498426; called by muse, mutect2, varscan2
- NLRP6 | c.897C>T p.F299= | Silent (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- RYR3 | c.10461G>A p.V3487= (on ENST00000389232; = p.V3488= on NM_001036.6) | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs1397802865; called by muse, mutect2, varscan2
- SLIT3 | c.2460C>T p.N820= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as rs142459392; called by muse, mutect2, varscan2
- SPEG | c.6339G>A p.A2113= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs766038129; called by muse, mutect2, varscan2
- STMN4 | c.75C>T p.A25= | Silent (SNP) | VAF 78/87 reads (90%) | catalogued as rs764779082; called by muse, mutect2, varscan2
- TMEM132B | c.1368G>A p.V456= | Silent (SNP) | VAF 42/85 reads (49%) | called by muse, mutect2, varscan2
- TTF1 | c.264G>A p.K88= | Silent (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2, varscan2
- ARHGAP5 | c.*4265T>C | 3'UTR (SNP) | VAF 19/36 reads (53%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.*75T>G | 3'UTR (SNP) | VAF 108/234 reads (46%) | called by muse, mutect2, varscan2
- CHRNA7 | c.880+69A>C | Intron (SNP) | VAF 21/38 reads (55%) | called by mutect2, varscan2
- CSPG5 | c.-240C>G | 5'UTR (SNP) | VAF 8/9 reads (89%) | called by muse, mutect2, varscan2
- DENND1A | c.*67T>C | 3'UTR (SNP) | VAF 10/40 reads (25%) | catalogued as rs984964821; called by muse, mutect2
- FAM20C | c.1445+39C>A | Intron (SNP) | VAF 49/125 reads (39%) | called by muse, mutect2, varscan2
- FFAR4 | c.*856A>T | 3'UTR (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- GRIN3B | c.*13G>A | 3'UTR (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- KIF6 | c.*770C>T | 3'UTR (SNP) | VAF 36/97 reads (37%) | called by muse, mutect2, varscan2
- LARP4B | c.*1343A>C | 3'UTR (SNP) | VAF 35/65 reads (54%) | called by muse, mutect2, varscan2
- LONRF2 | c.*2009T>C | 3'UTR (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- LPCAT2 | c.*1679A>T | 3'UTR (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
- LSG1 | c.1419+23A>G | Intron (SNP) | VAF 22/64 reads (34%) | called by mutect2, varscan2
- MARCKS | c.*220C>G | 3'UTR (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851321 A>C | 5'Flank (SNP) | VAF 49/87 reads (56%) | catalogued as rs1440026460; called by muse, mutect2, varscan2
- MSRB3 | c.*297del | 3'UTR (DEL) | VAF 14/33 reads (42%) | catalogued as rs1412386941; called by mutect2, pindel, varscan2
- NCKAP1 | c.2021+37G>A | Intron (SNP) | VAF 33/115 reads (29%) | called by muse, mutect2, varscan2
- PCBD1 | c.*294G>A | 3'UTR (SNP) | VAF 23/23 reads (100%) | catalogued as rs912662405; called by muse, mutect2, varscan2
- PPHLN1 | chr12:42448289 C>T | 3'Flank (SNP) | VAF 43/85 reads (51%) | called by muse, mutect2, varscan2
- PPP1R3D | c.*110C>T | 3'UTR (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- PTGES | c.*172G>T | 3'UTR (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- RAB6C | c.-405C>T | 5'UTR (SNP) | VAF 32/113 reads (28%) | called by muse, mutect2, varscan2
- RIN3 | c.440+70C>T | Intron (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2
- SESN3 | c.*4020T>C | 3'UTR (SNP) | VAF 31/83 reads (37%) | called by muse, mutect2, varscan2
- SIM2 | c.1576+685C>A | Intron (SNP) | VAF 30/115 reads (26%) | catalogued as rs1405707104; called by muse, mutect2, varscan2
- SPOCK3 | c.1-130C>T | Intron (SNP) | VAF 17/43 reads (40%) | catalogued as rs949394589; called by muse, mutect2, varscan2
- TFEC | c.*3659A>T | 3'UTR (SNP) | VAF 38/111 reads (34%) | catalogued as rs920467194, COSV55408918; called by muse, mutect2, varscan2
- TLK2 | c.*94T>C | 3'UTR (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- TRAPPC8 | c.-242_-238del | 5'UTR (DEL) | VAF 51/171 reads (30%) | called by mutect2, pindel, varscan2
- TTC6 | chr14:37792359 G>T | 5'Flank (SNP) | VAF 47/134 reads (35%) | called by muse, mutect2, varscan2
- ZIC1 | c.*3107T>A | 3'UTR (SNP) | VAF 44/125 reads (35%) | called by muse, mutect2, varscan2
- ZNF503-AS2 | n.556G>A | RNA (SNP) | VAF 26/54 reads (48%) | catalogued as rs1406266538; called by muse, mutect2, varscan2
- ZNF704 | c.*7121G>A | 3'UTR (SNP) | VAF 27/45 reads (60%) | called by muse, mutect2, varscan2
